Somatic mutation profile of tumor specimen TCGA-MH-A856-01A (aliquot TCGA-MH-A856-01A-11D-A34Z-10) from TCGA case TCGA-MH-A856, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 54.8 years (20,006 days).
Specimen TCGA-MH-A856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 071dbe17-a50b-4ea2-b7c4-239dbaab33f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MH-A856-10A (Blood Derived Normal), aliquot TCGA-MH-A856-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d178c03-1b60-4dd7-aad6-3bed75ce551b

The open-access MAF lists 75 somatic variants for this specimen: 55 protein-altering or splice-affecting, 15 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Frame Shift Del 7, Intron 4, Frame Shift Ins 3, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.1341G>A p.T447= | Splice Region (SNP) | VAF 14/33 reads (42%) | catalogued as rs1555630716, COSV100709653; called by muse, mutect2, varscan2
- ADCK2 | c.1073T>C p.V358A | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.113); catalogued as COSV99301565; called by muse, mutect2, varscan2
- ANGPTL4 | c.1169T>A p.L390Q | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100035097; called by muse, mutect2, varscan2
- ARHGAP32 | c.2119G>C p.E707Q (on ENST00000310343 / NM_001378025.1; = p.E358Q on NM_014715.4) | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV100087028, COSV59852061; called by muse, mutect2, varscan2
- BIRC2 | c.90T>G p.D30E | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99926655; called by muse, mutect2, varscan2
- BRINP2 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV64180164; called by muse, mutect2, varscan2
- CABLES1 | c.1012A>G p.I338V (on ENST00000256925 / NM_001100619.2; = p.I73V on NM_138375.2) | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); catalogued as rs749670341, COSV99908547; called by muse, mutect2, varscan2
- CHTF18 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374149034; called by muse, mutect2, varscan2
- COL11A2 | c.3777T>A p.D1259E (on ENST00000341947 / NM_080680.3; = p.D1152E on NM_080679.2) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.967); catalogued as COSV100553811; called by muse, mutect2, varscan2
- CREBBP | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.84); PolyPhen benign (0.011); catalogued as rs764674912, COSV99269649; called by muse, mutect2, varscan2
- DDHD2 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV101240612; called by muse, mutect2, varscan2
- DLAT | c.507-2A>T p.X169_splice | Splice Site (SNP) | VAF 23/65 reads (35%) | catalogued as COSV99734625; called by muse, mutect2, varscan2
- DLGAP4 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100211109; called by muse, mutect2, varscan2
- DMTF1 | c.1481T>G p.F494C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100487350, COSV100487482; called by muse, varscan2
- EIF4A2 | c.818T>C p.I273T | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV99961157; called by muse, mutect2, varscan2
- EIF5B | c.911C>A p.A304D | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99177173; called by muse, mutect2, varscan2
- EMC3 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV99793921; called by muse, mutect2, varscan2
- ESYT1 | c.3067A>G p.K1023E | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99919918; called by muse, mutect2, varscan2
- FOXP4 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV100332638; called by muse, mutect2, varscan2
- HCRTR1 | c.1231A>C p.I411L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV101035854; called by muse, mutect2, varscan2
- KDM4B | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99346227; called by muse, mutect2, varscan2
- KIAA1109 | c.10465G>A p.D3489N | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.984); catalogued as COSV52661545; called by muse, mutect2, varscan2
- KIF1A | c.2747A>G p.Q916R | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV100240640; called by muse, mutect2, varscan2
- LCK | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV100287634, COSV100287796; called by muse, mutect2
- LOXL4 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV99583812; called by muse, mutect2, varscan2
- LRP8 | c.2402T>G p.L801R | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV100036356; called by muse, mutect2, varscan2
- LSG1 | c.1612G>C p.D538H | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503188; called by muse, mutect2, varscan2
- MUTYH | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV100588010; called by muse, mutect2, varscan2
- NCDN | c.1342T>C p.S448P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.632); catalogued as COSV100621974; called by muse, mutect2
- PIGK | c.888A>C p.K296N | Missense Mutation (SNP) | VAF 83/211 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100769843; called by muse, mutect2, varscan2
- R3HDM1 | c.2578C>G p.H860D | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.058); catalogued as COSV99926100; called by muse, mutect2, varscan2
- RGS12 | c.2466T>G p.F822L | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100122813; called by muse, mutect2, varscan2
- SLC34A2 | c.161A>T p.Y54F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV101158287; called by muse, mutect2, varscan2
- SRCAP | c.2870G>A p.R957Q | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1215453424, COSV99349922; called by muse, mutect2, varscan2
- SSH2 | c.1519T>C p.F507L | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV99281893; called by muse, varscan2
- SUGP2 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.082); catalogued as COSV100431819; called by muse, mutect2
- TARS1 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.039); catalogued as rs761507268, COSV99465845; called by muse, mutect2, varscan2
- TMEM186 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99191130; called by muse, mutect2, varscan2
- TMEM213 | c.118C>A p.H40N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as COSV100023029; called by muse, mutect2, varscan2
- TRIM31 | c.929A>T p.K310I | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV100946785; called by muse, mutect2, varscan2
- TRIM43 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99719926; called by muse, mutect2, varscan2
- UTP4 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 82/214 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.296); catalogued as COSV100076932, COSV58733710; called by muse, mutect2, varscan2
- XPO5 | c.2509C>A p.Q837K | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99540789; called by muse, mutect2, varscan2
- ZMYM1 | c.1372A>C p.K458Q | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV100720960; called by muse, mutect2, varscan2
- ARG1 | c.468del p.D158Mfs*8 | Frame Shift Del (DEL) | VAF 38/146 reads (26%) | called by mutect2, pindel, varscan2
- CACNA2D1 | c.32dup p.T12Dfs*28 | Frame Shift Ins (INS) | VAF 19/69 reads (28%) | called by mutect2, pindel, varscan2
- DAZAP1 | c.658_659del p.G220Pfs*206 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.3126dup p.C1043Mfs*16 | Frame Shift Ins (INS) | VAF 18/63 reads (29%) | called by mutect2, pindel, varscan2
- HMG20A | c.138del p.N47Tfs*68 | Frame Shift Del (DEL) | VAF 64/190 reads (34%) | called by mutect2, varscan2
- MLLT6 | c.499G>C p.E167Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, varscan2
- MOCS2 | c.424del p.A142Pfs*10 | Frame Shift Del (DEL) | VAF 51/171 reads (30%) | called by mutect2, pindel, varscan2
- RAD23A | c.812del p.Q271Rfs*14 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel, varscan2
- SEMA3F | c.1398del p.I466Mfs*58 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- SLC17A8 | c.138del p.I46Mfs*3 | Frame Shift Del (DEL) | VAF 32/103 reads (31%) | called by mutect2, pindel, varscan2
- SLC25A11 | c.874dup p.H292Pfs*37 | Frame Shift Ins (INS) | VAF 17/47 reads (36%) | called by mutect2, pindel, varscan2
- ABCB10 | c.1587T>C p.S529= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs758903589, COSV100747920; called by muse, mutect2, varscan2
- ATP2C2 | c.1554C>T p.R518= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99297894; called by muse, mutect2, varscan2
- CIPC | c.870C>T p.S290= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100694449, COSV99075855; called by muse, mutect2, varscan2
- EFNA2 | c.267C>T p.Y89= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs561395362, COSV53066392; called by muse, mutect2, varscan2
- GON4L | c.348A>C p.I116= | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as COSV99674063; called by muse, mutect2, varscan2
- GPR155 | c.1371C>A p.T457= | Silent (SNP) | VAF 66/184 reads (36%) | catalogued as COSV55038098; called by muse, mutect2, varscan2
- GPR39 | c.234G>T p.S78= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100257598; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.750A>G p.G250= (on ENST00000354667 / NM_031243.3; = p.G238= on NM_002137.4) | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV100668240; called by muse, mutect2, varscan2
- JADE1 | c.2223T>A p.P741= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV99885658; called by muse, mutect2, varscan2
- JMJD4 | c.612G>C p.S204= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100248086; called by muse, mutect2, varscan2
- KDR | c.846G>A p.G282= | Silent (SNP) | VAF 51/130 reads (39%) | catalogued as COSV99817414; called by muse, mutect2, varscan2
- KRT5 | c.1314C>T p.A438= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV52863948, COSV99357963; called by muse, mutect2, varscan2
- PER2 | c.3666A>T p.P1222= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99611837; called by muse, mutect2, varscan2
- RASGRP4 | c.1422G>A p.V474= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99384956; called by muse, mutect2, varscan2
- TGOLN2 | c.471G>A p.E157= | Silent (SNP) | VAF 60/153 reads (39%) | catalogued as COSV99965024; called by muse, mutect2, varscan2
- CACNA1G | c.4422+95G>C | Intron (SNP) | VAF 17/39 reads (44%) | catalogued as COSV100661697; called by muse, mutect2, varscan2
- ERF | c.-2G>A | 5'UTR (SNP) | VAF 15/48 reads (31%) | catalogued as rs980956119, COSV55895459; called by muse, mutect2, varscan2
- IPO7 | c.1426-81C>G | Intron (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100797813; called by muse, mutect2, varscan2
- SLC25A3 | c.645-108T>C | Intron (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99499160; called by muse, mutect2, varscan2
- TBRG4 | c.907+116C>T | Intron (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99345371; called by muse, mutect2, varscan2
